Somatic mutation profile of tumor specimen MP2PRT-PAUPZB-TMP1-A (aliquot MP2PRT-PAUPZB-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUPZB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,083 days).
Specimen MP2PRT-PAUPZB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62e44202-1496-46e6-bda9-5e908b15f029.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPZB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPZB-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ce70fee-ca47-47d6-8675-2235be7cb0e6

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP6 | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV55212455; called by muse, mutect2, varscan2
- C5orf46 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs755537448; called by muse, mutect2
- CNTNAP3 | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 32/706 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1427108514, COSV52665237; called by muse, mutect2
- FSIP2 | c.16975G>T p.D5659Y | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100555986; called by muse, mutect2, varscan2
- GRM4 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 62/604 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.483); catalogued as rs202137326; called by muse, mutect2
- KRT23 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 55/622 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745920229, COSV52927172; called by muse, mutect2
- MGAM2 | c.5767C>T p.P1923S | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT tolerated, low confidence (0.3); catalogued as COSV72176422; called by muse, mutect2, varscan2
- MIPOL1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs780488483; called by muse, mutect2
- SNTG1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV52459237; called by muse, mutect2, varscan2
- TNFRSF13B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs764542734; called by muse, mutect2, varscan2
- TTC29 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV57274760; called by muse, mutect2
- ARHGEF38 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2
- ARMH2 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 50/413 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CFAP53 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- GRIA3 | c.2014G>A p.A672T | Missense Mutation (SNP) | VAF 44/675 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAGI1 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ULK1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK3 | c.2010C>T p.I670= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV56505209; called by muse, mutect2, varscan2
- EZHIP | c.1320G>A p.P440= | Silent (SNP) | VAF 76/830 reads (9%) | called by muse, mutect2
- FRMPD1 | c.723G>A p.E241= | Silent (SNP) | VAF 37/310 reads (12%) | called by muse, mutect2, varscan2
- GYG2 | c.426C>T p.S142= | Silent (SNP) | VAF 26/578 reads (4%) | called by muse, mutect2
- MYH13 | c.5349G>A p.L1783= | Silent (SNP) | VAF 47/449 reads (10%) | called by muse, mutect2, varscan2
- NYAP2 | c.1278C>T p.P426= | Silent (SNP) | VAF 64/479 reads (13%) | catalogued as rs1305682005; called by muse, mutect2, varscan2
- PDZD2 | c.7215C>T p.S2405= | Silent (SNP) | VAF 57/510 reads (11%) | catalogued as rs768918693, COSV56876735; called by muse, mutect2, varscan2
- TENT5B | c.570C>A p.I190= | Silent (SNP) | VAF 21/362 reads (6%) | called by muse, mutect2
- VSIG10L | c.2340C>T p.I780= | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as rs752884014, COSV54535444; called by muse, mutect2, varscan2
- MLIP | c.613-10819C>T | Intron (SNP) | VAF 35/241 reads (15%) | called by muse, mutect2, varscan2
